Gene-level copy-number profile of specimen HCM-CSHL-0379-C18-85C from HCMI case HCM-CSHL-0379-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,410 days).
Specimen HCM-CSHL-0379-C18-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d5e8c3d9-fa8d-48dd-83d4-571324470f89.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0379-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/ccd0a1de-5095-49aa-a9f2-e72c6bef8b18

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 5,869; copy number 3: 17,567; copy number 4: 21,908; copy number 5: 8,448; copy number 6: 3,319; copy number 7: 1,476; copy number 8: 148; copy number 9: 1; copy number 11: 17; copy number 39: 22; copy number 40: 2; copy number 50: 13; copy number 57: 116.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 171 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:22,406,019–22,706,703, 17 genes, copy number 11: FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr17:36,253,456–36,944,612, 22 genes, copy number 39 (within-gene range 4–39): TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J, ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1.
- chr17:38,297,023–40,975,926, 131 genes, copy number 40–57 (broad region; genes not listed).
- chr22:18,733,914–18,757,906, 1 gene, copy number 9: FAM230E.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
